Somatic mutation profile of tumor specimen C3L-04027-01 (aliquot CPT0254680006) from CPTAC case C3L-04027, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 69.5 years (25,375 days).
Specimen C3L-04027-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc5a5b66-0037-4bf5-a5a8-e9039c1f821f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04027-31 (Blood Derived Normal), aliquot CPT0254840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/262ff755-53a2-4b9b-ba95-0fda294e6f56

The open-access MAF lists 76 somatic variants for this specimen: 45 protein-altering or splice-affecting, 24 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 24, Intron 5, Nonsense Mutation 4, Frame Shift Del 2, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERCC6 | c.2047C>T p.R683* | Nonsense Mutation (SNP) | VAF 42/683 reads (6%) | catalogued as rs121917904, CM083633; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 140/783 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 52/820 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ADCY7 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 42/640 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs545059286, COSV54271135; called by muse, mutect2
- ALAS2 | c.1355G>T p.R452L | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.956); catalogued as CM970077; called by muse, mutect2, varscan2
- ASCC3 | c.5423G>A p.R1808H | Missense Mutation (SNP) | VAF 42/619 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.629); catalogued as rs371661297; called by muse, mutect2
- CDH22 | c.1270G>A p.A424T | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs1187606056; called by muse, mutect2
- COL9A3 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 100/1449 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745335790; called by muse, mutect2
- DLG4 | c.938G>A p.R313Q (on ENST00000399506 / NM_001321075.3; = p.R356Q on NM_001365.4) | Missense Mutation (SNP) | VAF 62/845 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.18); catalogued as rs764739020, COSV57238233; called by muse, mutect2
- DNAH10 | c.9556G>A p.E3186K (on ENST00000409039; = p.E3125K on NM_207437.3) | Missense Mutation (SNP) | VAF 36/363 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as rs757406131; called by muse, mutect2, varscan2
- DNAJC13 | c.4763G>A p.R1588H | Missense Mutation (SNP) | VAF 23/398 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.926); catalogued as rs145101163; called by muse, mutect2
- FAM170B | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 62/790 reads (8%) | catalogued as COSV61253742; called by muse, mutect2
- FREM2 | c.7005G>C p.E2335D | Missense Mutation (SNP) | VAF 62/1047 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54848801; called by muse, mutect2
- GLI2 | c.1294G>A p.D432N (on ENST00000361492 / NM_001374353.1; = p.D449N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/526 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs13427953, COSV58044729; called by muse, mutect2
- GNG2 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.427); catalogued as rs771997787; called by muse, mutect2
- HECTD4 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544019388; called by muse, mutect2
- HSPA12B | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 50/828 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs763936271, COSV99422358; called by muse, mutect2
- HTR1A | c.680G>A p.R227H | Missense Mutation (SNP) | VAF 81/1232 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs1427412024, COSV60500218; called by muse, mutect2
- ING1 | c.152G>C p.R51P | Missense Mutation (SNP) | VAF 29/345 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.997); catalogued as rs554816174, COSV100311959; called by muse, mutect2
- IRX6 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 34/556 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.103); catalogued as COSV51862486; called by muse, mutect2
- RNF180 | c.1275A>C p.E425D | Missense Mutation (SNP) | VAF 28/537 reads (5%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.549); catalogued as COSV66633903; called by muse, mutect2
- RPUSD1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761438615, COSV50101217; called by muse, mutect2
- SCYL3 | c.674T>C p.L225S | Missense Mutation (SNP) | VAF 24/451 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1283776031; called by muse, mutect2
- SDR42E2 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 42/612 reads (7%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.802); catalogued as rs1027761752; called by muse, mutect2
- SLC32A1 | c.1301C>T p.T434M | Missense Mutation (SNP) | VAF 46/452 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.095); catalogued as COSV54147145; called by muse, mutect2, varscan2
- STXBP1 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 68/1045 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749244650, CM1415061; ClinVar: uncertain significance; called by muse, mutect2
- USP22 | c.1117G>C p.E373Q | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54948064; called by muse, mutect2
- VASN | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 49/680 reads (7%) | catalogued as rs766706462; called by muse, mutect2
- ZIC3 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.579); catalogued as rs1198015588; called by muse, mutect2, varscan2
- ZNF469 | c.10900C>T p.R3634* (on ENST00000437464; = p.R3662* on NM_001367624.2) | Nonsense Mutation (SNP) | VAF 28/535 reads (5%) | catalogued as rs1171824548; ClinVar: uncertain significance; called by muse, mutect2
- ADAMTS19 | c.1849G>A p.G617R | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CES5A | c.1577G>A p.S526N (on ENST00000290567 / NM_001143685.2; = p.S476N on NM_145024.3) | Missense Mutation (SNP) | VAF 70/1054 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.673); called by muse, mutect2
- CYB561A3 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 44/701 reads (6%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.957); called by muse, mutect2
- FASTKD3 | c.1357C>T p.H453Y | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- MUC5B | c.16847del p.Y5616Sfs*12 | Frame Shift Del (DEL) | VAF 69/643 reads (11%) | called by mutect2, pindel*
- MYH7B | c.1046T>G p.M349R | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- NELL1 | c.2077C>G p.Q693E | Missense Mutation (SNP) | VAF 24/472 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2
- PAPPA | c.2450A>C p.K817T | Missense Mutation (SNP) | VAF 31/451 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.585); called by muse, mutect2
- PRPF6 | c.221A>G p.N74S | Missense Mutation (SNP) | VAF 49/802 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- PXDNL | c.4260G>T p.E1420D | Missense Mutation (SNP) | VAF 34/402 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2
- RNF43 | c.1133_1139del p.S378Cfs*39 | Frame Shift Del (DEL) | VAF 13/100 reads (13%) | called by mutect2, pindel, varscan2
- SELENOO | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 57/919 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRIM9 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 31/466 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.622); called by muse, mutect2
- WDR87 | c.485T>A p.I162N | Missense Mutation (SNP) | VAF 46/684 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZC3H12A | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 26/656 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ASXL1 | c.4182A>G p.E1394= | Silent (SNP) | VAF 37/507 reads (7%) | called by muse, mutect2
- CACNA1I | c.6267C>T p.S2089= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1349249848; called by muse, mutect2, varscan2
- CACNA2D2 | c.1671C>T p.Y557= | Silent (SNP) | VAF 43/778 reads (6%) | catalogued as rs370651951; called by muse, mutect2
- CBY2 | c.1008G>A p.G336= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs1292483864; called by muse, mutect2, varscan2
- CLIC3 | c.591G>A p.A197= | Silent (SNP) | VAF 40/392 reads (10%) | catalogued as rs376417159; called by muse, mutect2, varscan2
- COL6A3 | c.4404C>T p.I1468= | Silent (SNP) | VAF 62/806 reads (8%) | catalogued as rs371075249; ClinVar: uncertain significance; called by muse, mutect2
- CSMD2 | c.8019G>C p.L2673= | Silent (SNP) | VAF 37/444 reads (8%) | catalogued as rs759916101, COSV53930253; called by muse, mutect2
- DOCK2 | c.4512G>A p.T1504= | Silent (SNP) | VAF 18/321 reads (6%) | catalogued as rs376411478; ClinVar: uncertain significance; called by muse, mutect2
- FOXL1 | c.702G>A p.A234= | Silent (SNP) | VAF 30/281 reads (11%) | catalogued as rs766649546; called by muse, mutect2, varscan2
- HS6ST1 | c.144C>T p.R48= | Silent (SNP) | VAF 39/360 reads (11%) | called by muse, mutect2, varscan2
- ITGA9 | c.1185G>A p.A395= | Silent (SNP) | VAF 53/1023 reads (5%) | catalogued as rs753124626; called by muse, mutect2
- KCNA6 | c.528C>T p.I176= | Silent (SNP) | VAF 197/1097 reads (18%) | catalogued as COSV54973970; called by muse, mutect2, varscan2
- LCT | c.3873C>T p.Y1291= | Silent (SNP) | VAF 38/642 reads (6%) | called by muse, mutect2
- MAP1B | c.3456G>A p.T1152= | Silent (SNP) | VAF 23/276 reads (8%) | catalogued as rs145061898, COSV99701857; called by muse, mutect2
- MTMR11 | c.669C>T p.F223= (on ENST00000439741 / NM_001145862.2; = p.F151= on NM_181873.3) | Silent (SNP) | VAF 34/474 reads (7%) | catalogued as rs781940783, COSV63807448; called by muse, mutect2
- MUL1 | c.504T>C p.D168= | Silent (SNP) | VAF 32/380 reads (8%) | catalogued as rs964377314; called by muse, mutect2
- PAXBP1 | c.729T>G p.P243= | Silent (SNP) | VAF 37/738 reads (5%) | called by muse, mutect2
- RGS13 | c.333G>A p.R111= | Silent (SNP) | VAF 24/258 reads (9%) | called by muse, mutect2
- SEMA5A | c.2940C>T p.I980= | Silent (SNP) | VAF 52/799 reads (7%) | called by muse, mutect2
- SKI | c.1263C>T p.L421= | Silent (SNP) | VAF 59/781 reads (8%) | catalogued as rs773045410, COSV66013372; ClinVar: likely benign; called by muse, mutect2
- SPHKAP | c.3111T>G p.L1037= | Silent (SNP) | VAF 19/310 reads (6%) | called by muse, mutect2
- TCTE1 | c.627C>T p.G209= | Silent (SNP) | VAF 19/284 reads (7%) | catalogued as rs202138207, COSV101025273; called by muse, mutect2
- TMEM151A | c.876G>A p.S292= | Silent (SNP) | VAF 32/272 reads (12%) | catalogued as rs1446442597; called by muse, mutect2, varscan2
- TTN | c.26409T>C p.D8803= (on ENST00000591111; = p.D7876= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/178 reads (8%) | called by muse, mutect2
- C4A | c.2592+45A>C | Intron (SNP) | VAF 83/839 reads (10%) | called by muse, mutect2, varscan2
- CREBBP | c.4280+43G>A | Intron (SNP) | VAF 38/458 reads (8%) | catalogued as rs766857976; called by muse, mutect2
- LHX6 | chr9:122228292 C>T | 5'Flank (SNP) | VAF 60/892 reads (7%) | called by muse, mutect2
- LY6K | c.-74G>A | 5'UTR (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- NECAB3 | c.289+10C>G | Intron (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- SREBF1 | c.3214+39T>A | Intron (SNP) | VAF 49/724 reads (7%) | called by muse, mutect2
- VAV3 | c.1777+14088A>C | Intron (SNP) | VAF 32/546 reads (6%) | called by muse, mutect2
